Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3V2, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3V2-01A (Primary Tumor).

[page 1 of 2]
Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

History of papillary carcinoma on nodes biopsy from now for total thyroidectomy.

Specimens Submitted:

1: Thyroid gland; total thyroidectomy

DIAGNOSIS:

1. Thyroid gland; total thyroidectomy:

Tumor Type:

Papillary carcinoma, classical type

Histologic Grade:

Well differentiated

Mitotic Activity:

Not identified

Tumor Necrosis:

Not identified

Other Tumor Features:

Calcification of non-psammoma type

Tumor Location:

Right lobe

Tumor Size:

Greatest diameter is 2.1 cm.

Tumor Encapsulation:

Partially surrounded

Blood Vessel Invasion:

Areas suggestive but not diagnostic
(adjacent to the 0.8 cm microcarcinoma in the left lobe)

Extrathyroid Extension:

Not identified

Surgical Margins:

Free of tumor

Tumor Multicentricity:

Gross foci present

Papillary microcarcinomas, two foci: 0.9 cm in greatest dimension (right lobe), and 0.8 cm in greatest dimension (left lobe)

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9

5-2-12
20

[page 2 of 2]
Adenoma(s) (away from the carcinoma):

Not Identified

Non-Neoplastic Thyroid:

Exhibits severe chronic lymphocytic thyroiditis

Parathyroid Glands:

Not Identified

Lymph Nodes:

Metastatic papillary thyroid carcinoma to 1 of 4 perithyroidal lymph nodes (1/4); Positive lymph node (left side) measures 0.9 cm in greatest dimension; Metastatic tumor deposit measures 0.6 cm in greatest dimension; No extranodal extension.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). Received fresh without fixative labeled "thyroid gland" is 22g thyroid. The right lobe measures 5.1 x 2.1 x 1.5 cm, the left lobe measures 5.0 x 2.1 x 2.1 cm and the isthmus measures 3.1 x 1.3 x 0.5 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals multiple nodules in both the left and right lobes. The largest nodule is in the right lobe (nodule one) which is 2.1 x 2.1 x 1.9 cm and has a glistening multicystic cut surface. Superior to the nodule #1 is a 0.9 x 0.8 x 0.8 cm nodule with a brown tan cut surface (nodule two). In the left lobe there is a 0.8 x 0.6 x 0.4 cm nodule with a white-tan cut surface (nodule three). The remaining thyroid parenchyma is red brown and beefy. The specimen is entirely submitted for diagnosis and

Summary of sections:

N1 - nodule one, entirely submitted, from superior to inferior
N2 - nodule two, entirely submitted, from superior to inferior
N3 - nodule three, entirely submitted, from superior to inferior
RL - remaining right lobe
LL - remaining left lobe
IS - isthmus

Summary of Sections:

Part 1: Thyroid gland; total thyroidectomy

Block	Sect. Site	PCs
2	I	2
1	LL	1
5	N1	5
2	N2	2
6	N3	6
1	RL	1

Source: NCI Genomic Data Commons file b3b16c85-bfa8-492f-843e-03d8fbd501f9 (TCGA-DJ-A3V2.7F24A721-5F52-4FEE-B832-3CC0614C9E46.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).